Somatic mutation profile of tumor specimen TCGA-IG-A3I8-01A (aliquot TCGA-IG-A3I8-01A-11D-A247-09) from TCGA case TCGA-IG-A3I8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 51.4 years (18,786 days).
Specimen TCGA-IG-A3I8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 583db8cc-ce27-4f2c-bbb6-f1c9e1af7849.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3I8-10A (Blood Derived Normal), aliquot TCGA-IG-A3I8-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e24e90fe-6f6e-445a-875a-031a2bfbcd7f

The open-access MAF lists 100 somatic variants for this specimen: 72 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 27, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOBOX | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as rs1218620893, COSV56195066; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/33 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADCY10 | c.3244G>A p.D1082N | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs778523169; called by muse, varscan2
- AHNAK2 | c.3176C>A p.A1059D | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.39); catalogued as rs779782626; called by muse, mutect2
- AK9 | c.3476G>A p.R1159H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774061625, COSV58137283; called by muse, mutect2, varscan2
- ANK3 | c.10748C>T p.T3583M | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV55042774; called by muse, mutect2, varscan2
- AOX1 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.148); catalogued as COSV65979860; called by muse, mutect2, varscan2
- ARVCF | c.2872G>A p.V958I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.355); catalogued as rs72554700; called by muse, mutect2, varscan2
- BRD2 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66373038; called by muse, mutect2, varscan2
- CCL20 | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.153); catalogued as COSV62591303; called by muse, varscan2
- CDH7 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 86/125 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59881758; called by muse, mutect2, varscan2
- CHAF1A | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573779621, COSV100011346; called by muse, mutect2, varscan2
- CHSY1 | c.1565C>G p.S522W | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs751688006; called by muse, mutect2, varscan2
- COX8C | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs746074705; called by muse, mutect2, varscan2
- CRACDL | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs775652941, COSV67409061; called by muse, mutect2
- DPP6 | c.2434G>A p.A812T (on ENST00000377770 / NM_001364500.2; = p.A750T on NM_001936.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV100123195; called by muse, mutect2, varscan2
- EZHIP | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1557318879, COSV100539415; called by muse, mutect2
- GNPTAB | c.1999G>C p.E667Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as CM094378, COSV100171690; called by muse, varscan2
- HOOK2 | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs370952243, COSV104393244; called by muse, mutect2, varscan2
- IL22RA1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs751761313; called by muse, mutect2, varscan2
- IQCE | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs762486693, COSV58078203; called by muse, mutect2, varscan2
- IRAG1 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs373371120, COSV101351693; called by muse, mutect2, varscan2
- KCNT2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778987960, COSV54081501, COSV54090551; called by muse, mutect2, varscan2
- LRRC61 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs757569479; called by muse, mutect2, varscan2
- MAGEB6 | c.1202G>C p.R401T | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV66872649; called by muse, mutect2, varscan2
- MRPS15 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as rs940094284; called by muse, mutect2, varscan2
- OBSCN | c.15644G>A p.R5215H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375864261, CM1513514; called by muse, mutect2, varscan2
- ODF2 | c.1487G>A p.R496H (on ENST00000434106 / NM_153433.2; = p.R472H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs1196089985, COSV63546661; called by muse, mutect2, varscan2
- OR8J3 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs752411061, COSV56879525; called by muse, mutect2, varscan2
- PCYT1B | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs984666694; called by muse, mutect2, varscan2
- PHF21A | c.674C>T p.T225I (on ENST00000418153 / NM_001101802.3; = p.T226I on NM_016621.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV57659302; called by muse, mutect2, varscan2
- PLCL1 | c.1076G>T p.R359I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as rs1429970146; called by muse, mutect2, varscan2
- PRDM16 | c.2320G>T p.D774Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV54586439, COSV99576294; called by muse, mutect2, varscan2
- PRRC2B | c.6023G>T p.S2008I | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV57645918; called by muse, mutect2, varscan2
- SNTA1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.072); catalogued as rs771369802; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN2 | c.5488C>T p.R1830C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1032630878, COSV59459989; called by muse, mutect2, varscan2
- TTN | c.2996G>A p.R999H (on ENST00000591111; = p.R953H on NM_003319.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | PolyPhen probably damaging (0.95); catalogued as rs371757623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZC3H12B | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.549); catalogued as rs969279759; called by muse, mutect2, varscan2
- ACSS3 | c.1289T>C p.V430A | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- CDH19 | c.2105A>G p.K702R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.997); called by muse, mutect2
- DSEL | c.335C>G p.T112R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- ERBB3 | c.3197G>T p.C1066F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM126B | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GIGYF2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GLUD2 | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HEATR4 | c.2690G>A p.G897E | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF22 | c.681G>C p.K227N | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KHNYN | c.195_196del p.R65Sfs*16 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by pindel, varscan2
- KLHL26 | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- LILRA6 | c.533_544del p.Q178_F181del | In Frame Del (DEL) | VAF 5/32 reads (16%) | called by mutect2, varscan2
- LILRB3 | c.1751G>C p.R584T (on ENST00000346401; = p.R572T on NM_006864.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYT1L | c.1249T>C p.S417P | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAALAD2 | c.452A>T p.Y151F | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR4D5 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTUD4 | c.2330A>T p.N777I (on ENST00000447906 / NM_001366057.1; = p.N712I on NM_001102653.1) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- OTUD6B | c.821T>G p.L274* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- PAPPA2 | c.2650T>G p.C884G | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDE11A | c.1713G>C p.W571C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); called by muse, varscan2
- PDPR | c.35G>A p.R12K | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSME4 | c.2883A>T p.K961N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- REG3G | c.437G>T p.C146F | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SATB2 | c.780G>C p.Q260H | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2
- SESTD1 | c.1283-1G>C p.X428_splice | Splice Site (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- SLC12A8 | c.736G>T p.G246* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- SLC9A5 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SNAI2 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TBXA2R | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TNC | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNIK | c.1646del p.P549Lfs*48 | Frame Shift Del (DEL) | VAF 12/16 reads (75%) | called by mutect2, varscan2
- TNNI3K | c.2272A>G p.S758G | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.039); called by muse, mutect2
- TRPC5 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ZNF91 | c.3180A>G p.I1060M | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ACSS1 | c.1686C>T p.T562= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs779037733, COSV100054143, COSV60217884; called by muse, mutect2
- ADAMTSL1 | c.2499G>A p.P833= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs760762246, COSV65888757; called by muse, mutect2, varscan2
- ARHGEF10 | c.1923C>T p.L641= (on ENST00000398564; = p.L616= on NM_014629.4) | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as rs146717173; called by muse, mutect2, varscan2
- CDK13 | c.1401C>T p.A467= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs137937704; ClinVar: likely benign; called by muse, mutect2
- COL6A3 | c.4059C>T p.D1353= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs765355858, COSV55103114; called by muse, mutect2, varscan2
- DNAH10 | c.330A>G p.L110= (on ENST00000409039; = p.L49= on NM_207437.3) | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV101292524; called by muse, mutect2, varscan2
- DNAJC12 | c.198G>A p.L66= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- DST | c.3798A>G p.Q1266= (on ENST00000361203 / NM_001374722.1; = p.Q940= on NM_001723.6) | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs766624513; called by muse, mutect2, varscan2
- DUOXA2 | c.120C>T p.L40= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs757519712; called by muse, mutect2, varscan2
- ESR2 | c.906C>T p.A302= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs1221882618, COSV99963021; called by muse, mutect2, varscan2
- FCRL4 | c.1140C>T p.T380= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- GLI3 | c.2712C>T p.R904= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs1196667217, COSV67892441, COSV67892934; called by muse, mutect2, varscan2
- MAP3K1 | c.4413A>G p.P1471= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs760319082; called by muse, mutect2, varscan2
- MC5R | c.630C>T p.L210= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs1232581874; called by muse, mutect2, varscan2
- NEBL | c.2049G>A p.L683= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV65804036; called by muse, mutect2
- NINL | c.4065G>A p.E1355= | Silent (SNP) | VAF 18/90 reads (20%) | called by muse, varscan2
- NINL | c.4023G>A p.V1341= | Silent (SNP) | VAF 17/84 reads (20%) | called by muse, varscan2
- OR5L2 | c.717C>A p.S239= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs1216837341, COSV65724009; called by muse, mutect2, varscan2
- OR5R1 | c.333G>A p.E111= | Silent (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2
- PKP4 | c.2736C>T p.Y912= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs138568714; called by muse, mutect2, varscan2
- PPP4R4 | c.1279C>T p.L427= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2, varscan2
- RRN3 | c.1629C>T p.T543= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs773259277, COSV52213453; called by muse, mutect2, varscan2
- TDO2 | c.588G>A p.E196= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs773821631; called by muse, mutect2, varscan2
- TIGIT | c.483C>A p.V161= | Silent (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- TUBA3C | c.1152C>T p.I384= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs1052403; called by muse, mutect2, varscan2
- UPF3B | c.588G>A p.K196= | Silent (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- ZNF582 | c.1119A>G p.G373= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- AC024598.1 | c.1130-850C>T | Intron (SNP) | VAF 11/34 reads (32%) | catalogued as rs141356718; called by muse, mutect2, varscan2
